CCDI case PBBTNU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/7d4fac26-0b40-4935-ac42-6029515f95ec

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 16.6 years (6,074 days).

Biospecimens (3 samples)
- Sample 0DGOA0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGOAT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DGOBB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
